HCMI case HCM-SANG-1307-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/2d0b1976-6a09-4623-a32c-eed22e944dbf

Demographics
Sex at birth: female; Days to birth: -19,540 days (53.5 years before the index date).

Diagnoses (1)
1. Carcinoma, undifferentiated, NOS: ICD-O-3 morphology code: 8020/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Tumor grade: G1; Prior malignancy: yes; Prior treatment: No; Uicc clinical stage: Stage IIB; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIB; Uicc pathologic t: T2; Uicc staging system edition: 7th.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 25.
   Recorded as not given: neoadjuvant treatment (type not reported).

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-SANG-1307-C25-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-1307-C25-85A-01D-A80T-32, HCM-SANG-1307-C25-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
